Somatic mutation profile of tumor specimen TCGA-BR-4253-01A (aliquot TCGA-BR-4253-01A-01D-1126-08) from TCGA case TCGA-BR-4253, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 80.5 years (29,397 days).
Specimen TCGA-BR-4253-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9fe62ce-2744-4c21-af51-f7c8a2ee5526.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4253-11A (Solid Tissue Normal), aliquot TCGA-BR-4253-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbc9bffa-8fdf-4f67-a810-aa6cde78c444

The open-access MAF lists 95 somatic variants for this specimen: 73 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 20, Frame Shift Del 5, Nonsense Mutation 4, Splice Site 2, In Frame Del 1, RNA 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.4280C>T p.T1427M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs182925368, COSV52193468; called by mutect2, varscan2
- ADD1 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); catalogued as rs757890985, COSV53270879; called by mutect2, varscan2
- AHNAK2 | c.15939G>A p.M5313I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV60920761; called by muse, mutect2, varscan2
- ARID1A | c.4024C>T p.Q1342* | Nonsense Mutation (SNP) | VAF 82/215 reads (38%) | catalogued as COSV61381745; called by muse, mutect2, varscan2
- BEST2 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs371801091; called by muse, mutect2, varscan2
- BMS1 | c.1694A>C p.K565T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV65734488; called by muse, mutect2, varscan2
- BMS1 | c.1833G>C p.E611D | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV65733739, COSV65734493; called by muse, mutect2, varscan2
- C20orf194 | c.2804T>G p.L935R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52698340; called by muse, mutect2, varscan2
- CASP10 | c.1100C>T p.S367L (on ENST00000272879 / NM_032974.5; = p.S324L on NM_001230.5) | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs774726645, COSV53779277; called by muse, mutect2, varscan2
- CD58 | c.152T>A p.L51* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV65665055; called by muse, mutect2, varscan2
- CFAP20DC | c.1457C>G p.S486* (on ENST00000482387 / NM_001351530.2; = p.S361* on NM_198463.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/109 reads (14%) | catalogued as COSV55922721; called by muse, mutect2, varscan2
- CHRND | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51323523; called by muse, mutect2, varscan2
- COL4A2 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.886); catalogued as rs777186602, COSV64630270; called by muse, mutect2, varscan2
- EDEM3 | c.2432A>T p.D811V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.33); catalogued as COSV58925802; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- ELL2 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV52983656; called by muse, mutect2
- EYA1 | c.1602A>C p.K534N | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58167021; called by muse, mutect2, varscan2
- FBN2 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs199587570, COSV52493380; called by muse, mutect2, varscan2
- GNAS | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as CM150178, COSV55672684; called by muse, mutect2, varscan2
- GPRASP1 | c.2460G>C p.E820D | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.412); catalogued as COSV64355979; called by muse, mutect2, varscan2
- GREB1 | c.1778C>T p.T593M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373848439; called by mutect2, varscan2
- GRM5 | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59613504; called by muse, mutect2, varscan2
- ILDR1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs148962924; called by mutect2, varscan2
- ITGA11 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.272); catalogued as rs995830321, COSV100241530, COSV59879420; called by muse, mutect2, varscan2
- KIF6 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as rs1352502916, COSV54683951; called by muse, mutect2, varscan2
- KLHL4 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs754779267, COSV64143000, COSV64147175; called by muse, mutect2, varscan2
- LOX | c.1247+1G>A p.X416_splice | Splice Site (SNP) | VAF 15/88 reads (17%) | catalogued as rs1233555524, COSV50236868; called by muse, mutect2, varscan2
- MAGI2 | c.3010C>A p.L1004I | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62676008; called by muse, mutect2, varscan2
- MEIS3 | c.862C>T p.P288S (on ENST00000558555 / NM_001346148.1; = p.P334S on NM_020160.3) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV58984076; called by muse, mutect2, varscan2
- MUC16 | c.39381T>G p.G13127= | Splice Region (SNP) | VAF 14/118 reads (12%) | catalogued as COSV66694211; called by mutect2, varscan2
- MUC17 | c.4613C>T p.P1538L | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1227668638, COSV60294285; called by muse, mutect2, varscan2
- MYO1B | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs139382265; called by muse, mutect2, varscan2
- NEK10 | c.1835T>C p.L612P | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58285852; called by muse, mutect2, varscan2
- NLRP5 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537471101, COSV66762321; called by muse, mutect2, varscan2
- OPN5 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.289); catalogued as COSV55246293; called by muse, mutect2, varscan2
- OR10P1 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV59007671; called by muse, mutect2, varscan2
- OR2T4 | c.719T>G p.L240R | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV63544465, COSV63544829; called by muse, mutect2, varscan2
- OR52E6 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100259345, COSV61432520; called by muse, mutect2
- OR9G1 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.259); catalogued as COSV100380234, COSV56451966; called by muse, mutect2, varscan2
- P2RY12 | c.245T>G p.L82R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56385459; called by muse, mutect2, varscan2
- PCDHGA11 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.133); catalogued as COSV53914568; called by muse, mutect2, varscan2
- PDZD2 | c.1564A>C p.M522L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV56863548; called by muse, mutect2, varscan2
- PLP2 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66240152; called by muse, mutect2
- PODN | c.913del p.A305Pfs*5 (on ENST00000395871; = p.A257Pfs*5 on NM_153703.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | catalogued as COSV57016014; called by mutect2, pindel, varscan2
- PPP2R2B | c.86C>T p.T29M (on ENST00000394409; = p.T95M on NM_181674.2) | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371779801; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 59/133 reads (44%) | catalogued as rs146650273; called by pindel, varscan2
- RELN | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 46/187 reads (25%) | catalogued as COSV58985849, COSV59014511; called by muse, mutect2, varscan2
- SEC63 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs773658254, COSV64600752; called by muse, mutect2, varscan2
- SETD1A | c.1174C>A p.P392T | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs771871764, COSV52689654; called by muse, mutect2, varscan2
- SLAMF1 | c.821A>G p.E274G | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs201439748, COSV52497370, COSV52497507; called by muse, varscan2
- SNCAIP | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 34/329 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs143440334; called by muse, mutect2, varscan2
- SORCS1 | c.1375A>G p.R459G | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV53880769, COSV99545241; called by muse, mutect2, varscan2
- SPEF2 | c.4592A>C p.E1531A | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV57430330; called by muse, mutect2, varscan2
- SSBP4 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765372134, COSV54211175; called by muse, mutect2, varscan2
- SYT4 | c.1076T>C p.V359A | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.881); catalogued as rs755706111, COSV54901782; called by muse, mutect2, varscan2
- TDRD1 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1432825610, COSV52592616; called by muse, mutect2, varscan2
- TLR5 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.902); catalogued as rs201906412, COSV60559266; called by muse, mutect2, varscan2
- TMEM63C | c.782A>T p.N261I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV100029482; called by muse, mutect2, varscan2
- USH2A | c.1529A>T p.D510V | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100236511; called by muse, mutect2, varscan2
- WDR88 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV63451918; called by muse, mutect2, varscan2
- YTHDF1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV64833390; called by muse, mutect2, varscan2
- ZEB2 | c.2549C>T p.S850F | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.364); catalogued as rs529220318, COSV57960356; called by muse, mutect2, varscan2
- ZNF492 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV71762132; called by muse, varscan2
- ZNF492 | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1420552954, COSV71762133; called by muse, varscan2
- ZWINT | c.623+1G>A p.X208_splice | Splice Site (SNP) | VAF 17/109 reads (16%) | catalogued as rs1291949061, COSV59185960; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.194A>C p.E65A | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- IGHV2-26 | c.278A>G p.D93G | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGLV1-36 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- NDUFS1 | c.25_45del p.A9_K15del | In Frame Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel
- PCDH11X | c.370_413del p.K124Vfs*19 | Frame Shift Del (DEL) | VAF 19/104 reads (18%) | called by mutect2, pindel
- TMEM236 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 121/610 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TUBGCP3 | c.2087del p.E696Gfs*60 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- AIDA | c.786G>A p.E262= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV60514726; called by muse, mutect2, varscan2
- ARHGAP24 | c.534C>A p.G178= (on ENST00000395184 / NM_001025616.3; = p.G85= on NM_031305.3) | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV51990828; called by muse, mutect2, varscan2
- CHRNA2 | c.1053T>C p.N351= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV53558427; called by muse, mutect2, varscan2
- DPYS | c.690G>A p.T230= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs374805521, COSV60907028; called by mutect2, varscan2
- FAT4 | c.10455T>G p.V3485= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV58694362, COSV58712752; called by muse, mutect2, varscan2
- FBXO40 | c.2028T>G p.T676= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as COSV57525438; called by muse, mutect2, varscan2
- GABRA4 | c.984T>G p.A328= | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as COSV51930774; called by muse, mutect2, varscan2
- KCNU1 | c.2652C>G p.L884= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV67757595; called by muse, mutect2, varscan2
- KIAA1210 | c.4029G>A p.Q1343= | Silent (SNP) | VAF 68/475 reads (14%) | catalogued as COSV68178195; called by muse, varscan2
- MARK2 | c.1689G>A p.Q563= (on ENST00000402010 / NM_001039469.2; = p.Q508= on NM_004954.5) | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV59285531; called by muse, mutect2, varscan2
- MOV10 | c.2451G>A p.K817= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs749104311, COSV53518356; called by mutect2, varscan2
- NCAM1 | c.591G>A p.G197= | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as COSV57519735; called by muse, mutect2
- NCKAP5 | c.1656A>C p.P552= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as COSV58456059; called by muse, mutect2, varscan2
- OR10H2 | c.369C>T p.Y123= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs1326124650, COSV59946427; called by muse, mutect2, varscan2
- PARP15 | c.2019C>T p.L673= (on ENST00000464300 / NM_001113523.3; = p.L439= on NM_152615.2) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1196856077, COSV100117186, COSV59973452; called by muse, mutect2, varscan2
- PGA3 | c.45C>T p.C15= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV57711874; called by muse, mutect2, varscan2
- PRKAG2 | c.1494T>G p.L498= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV55233360; called by muse, mutect2, varscan2
- RBM48 | c.849G>A p.E283= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV56003106; called by muse, mutect2, varscan2
- TRMT9B | c.648C>A p.G216= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV71600484; called by muse, mutect2, varscan2
- VCX3A | c.552G>A p.P184= | Silent (SNP) | VAF 76/298 reads (26%) | catalogued as rs778548663, COSV101129971, COSV66910759; called by muse, varscan2
- GPR101 | c.*2G>A | 3'UTR (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- OFCC1 | n.316C>T | RNA (SNP) | VAF 17/91 reads (19%) | catalogued as rs145100001; called by muse, mutect2, varscan2
